Somatic mutation profile of tumor specimen ALCH-B1JW-TTP1-A (aliquot ALCH-B1JW-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1JW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 71.1 years (25,986 days).
Specimen ALCH-B1JW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f01db8e2-2eb2-4831-862b-5f4bd857c18d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1JW-NB1-A (Blood Derived Normal), aliquot ALCH-B1JW-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07224fb5-bb80-4c41-87b2-c625d0c2a80e

The open-access MAF lists 385 somatic variants for this specimen: 262 protein-altering or splice-affecting, 71 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 224, Silent 71, Intron 21, Nonsense Mutation 20, 5'UTR 8, RNA 7, 3'UTR 7, Frame Shift Del 6, 5'Flank 5, Splice Site 4, Splice Region 4, 3'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375+1G>A p.X125_splice | Splice Site (SNP) | VAF 19/86 reads (22%) | hotspot (GDC flag); catalogued as rs1567555445, CS951538, COSV52663569, COSV52668477, COSV52702628; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ACBD5 | c.1348G>T p.A450S (on ENST00000375888 / NM_001352568.1; = p.A441S on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101022429, COSV65521536; called by muse, mutect2, varscan2
- ACE | c.2858G>T p.R953L | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99326256; called by muse, mutect2, varscan2
- ACSM3 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as rs370404111; called by muse, mutect2
- ACY1 | c.921+5G>A | Splice Region (SNP) | VAF 12/72 reads (17%) | catalogued as rs1246957628; called by muse, mutect2
- ADAD1 | c.1598G>T p.G533V | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV56648326; called by muse, mutect2, varscan2
- ADAMTS5 | c.1483C>A p.Q495K | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53178891; called by muse, mutect2, varscan2
- ADGRB3 | c.3854C>T p.T1285M | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs776438259, COSV53259387; called by muse, mutect2, varscan2
- ADGRG4 | c.4025C>A p.T1342N | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs1169107881, COSV54955150; called by muse, mutect2, varscan2
- ARRB1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV63575290; called by muse, mutect2, varscan2
- ASPM | c.3406G>T p.V1136L | Missense Mutation (SNP) | VAF 67/397 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1255706246; called by muse, mutect2, varscan2
- ATP8A1 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.513); catalogued as COSV52541737; called by muse, mutect2, varscan2
- BRINP3 | c.2164G>T p.D722Y | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV66541081; called by muse, mutect2, varscan2
- C22orf23 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs146120637; called by muse, mutect2, varscan2
- CACNA1A | c.5200G>T p.D1734Y | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV64213219; called by muse, mutect2, varscan2
- CARTPT | c.183G>C p.L61F | Missense Mutation (SNP) | VAF 87/353 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909065, CM013060; ClinVar: risk factor; called by muse, mutect2, varscan2
- CCDC81 | c.426A>C p.Q142H | Missense Mutation (SNP) | VAF 61/375 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV53581739; called by muse, mutect2, varscan2
- CDKN2A | c.341C>G p.P114R | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM983988, COSV58683051, COSV58690307, COSV58692178; called by muse, mutect2, varscan2
- CETN1 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 18/124 reads (15%) | catalogued as COSV59121971; called by muse, mutect2, varscan2
- CETP | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 67/364 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1168321565; called by muse, mutect2, varscan2
- CFAP97 | c.602C>G p.S201C | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs573072306, COSV57112892; called by muse, mutect2, varscan2
- CFHR5 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.565); catalogued as rs868282962; called by muse, mutect2, varscan2
- CHEK1 | c.792G>A p.W264* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as rs1470286568; called by muse, mutect2, varscan2
- COL11A1 | c.3925G>T p.G1309C | Missense Mutation (SNP) | VAF 49/323 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV62194559; called by muse, mutect2, varscan2
- CSDE1 | c.1441A>G p.T481A (on ENST00000358528 / NM_001007553.3; = p.T450A on NM_007158.6) | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs200194985; called by muse, mutect2, varscan2
- CSMD3 | c.9850C>T p.P3284S (on ENST00000297405 / NM_001363185.1; = p.P3115S on NM_052900.3) | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs749009299, COSV52189370; called by muse, mutect2, varscan2
- CYLC1 | c.274A>G p.T92A | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs767796942; called by muse, mutect2, varscan2
- DLC1 | c.305C>G p.A102G | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as rs772894753, COSV52306666; called by muse, mutect2, varscan2
- DLG2 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 50/284 reads (18%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.017); catalogued as COSV101073189; called by muse, mutect2, varscan2
- DNAH3 | c.11608G>A p.E3870K | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54509512; called by muse, mutect2, varscan2
- DNAH6 | c.6136C>T p.R2046W | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs777912858; called by muse, mutect2, varscan2
- DNAH7 | c.7585G>T p.G2529C | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs754326341, COSV100413688; called by muse, mutect2, varscan2
- DNER | c.1997G>C p.R666P | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59160945, COSV59173630; called by muse, mutect2, varscan2
- DST | c.9986A>G p.Y3329C | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772873897; called by muse, mutect2, varscan2
- EML5 | c.2072G>T p.R691L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779121960, COSV61342946, COSV61345310; called by muse, mutect2
- FMN2 | c.2773C>A p.P925T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.243); catalogued as COSV60432669, COSV60449587; called by muse, mutect2, varscan2
- GAD2 | c.1310A>G p.Y437C | Missense Mutation (SNP) | VAF 42/292 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775115743; called by muse, mutect2, varscan2
- GDNF | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 53/318 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58480538; called by muse, mutect2, varscan2
- GRM7 | c.2555C>T p.P852L | Missense Mutation (SNP) | VAF 76/446 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63147175; called by muse, mutect2, varscan2
- HOXA9 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.026); catalogued as rs765931391; called by muse, mutect2, varscan2
- IGKV1D-43 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 48/345 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs751263281; called by muse, mutect2, varscan2
- ITK | c.1069G>T p.V357L | Missense Mutation (SNP) | VAF 66/373 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV70064313; called by muse, mutect2, varscan2
- KCNH8 | c.1806C>A p.S602R | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.752); catalogued as COSV100109272; called by muse, mutect2
- KCNIP3 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 5/36 reads (14%) | catalogued as rs1490567802; called by muse, mutect2, varscan2
- KCNQ2 | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as CM136080, COSV100610433; called by muse, mutect2, varscan2
- KLHL1 | c.2020G>T p.D674Y | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64769087; called by muse, mutect2, varscan2
- LRRK1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV99441833; called by muse, mutect2, varscan2
- MMACHC | c.763C>T p.P255S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs533256855; called by muse, mutect2
- MROH2B | c.3883C>A p.L1295I | Missense Mutation (SNP) | VAF 108/224 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV101270440; called by muse, mutect2, varscan2
- MSTO1 | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs139011201; called by muse, mutect2, varscan2
- NACAD | c.866G>T p.G289V | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs1372431486; called by muse, mutect2, varscan2
- NCOA2 | c.2689A>G p.T897A | Missense Mutation (SNP) | VAF 75/434 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs200846291, COSV51219051; called by muse, mutect2, varscan2
- NOTCH3 | c.5242C>T p.R1748C | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs775425174, COSV54629672; called by muse, mutect2, varscan2
- NPAS3 | c.328G>T p.G110W (on ENST00000356141 / NM_001164749.2; = p.G80W on NM_022123.3) | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58073789; called by muse, mutect2, varscan2
- NPAS3 | c.329G>T p.G110V (on ENST00000356141 / NM_001164749.2; = p.G80V on NM_022123.3) | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58071144; called by muse, mutect2, varscan2
- NRXN1 | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.969); catalogued as COSV58466870; called by muse, mutect2, varscan2
- OR2T6 | c.605G>T p.C202F | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63216473; called by muse, mutect2, varscan2
- OR4C12 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV58859666; called by muse, varscan2
- OR52N4 | c.778T>C p.S260P | Missense Mutation (SNP) | VAF 75/506 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1490307281; called by muse, mutect2, varscan2
- OR8I2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs773934404, COSV56166825, COSV56168276; called by muse, mutect2, varscan2
- OR9Q1 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs143309382, COSV59047646; called by mutect2, varscan2
- PAPOLG | c.1458T>G p.H486Q | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs757956370; called by muse, mutect2, varscan2
- PCDH15 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57378887; called by muse, mutect2, varscan2
- PCDHA9 | c.1844C>T p.T615M | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as rs555417773, COSV65334252; called by muse, mutect2, varscan2
- PCDHB13 | c.1664A>G p.N555S | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as rs568642398; called by muse, mutect2
- PCDHB5 | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV50668995; called by muse, mutect2, varscan2
- PRB2 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as rs759081917; called by muse, mutect2
- PRDM15 | c.1376C>A p.S459* | Nonsense Mutation (SNP) | VAF 3/15 reads (20%) | catalogued as COSV99519390; called by muse, mutect2
- PROS1 | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 14/132 reads (11%) | catalogued as COSV101260460; called by muse, mutect2, varscan2
- PRPF40A | c.1081A>G p.T361A | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.201); catalogued as rs746439673; called by muse, mutect2, varscan2
- RAD54L2 | c.3848C>T p.P1283L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as rs938327194; called by muse, varscan2
- RASGEF1A | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65666896; called by muse, mutect2, varscan2
- RELN | c.3182C>G p.P1061R | Missense Mutation (SNP) | VAF 58/359 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100634718; called by muse, mutect2, varscan2
- RPS24 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs948332181; called by muse, mutect2, varscan2
- RYR1 | c.6078G>T p.E2026D | Missense Mutation (SNP) | VAF 48/316 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as COSV62090990; called by muse, mutect2, varscan2
- RYR2 | c.8390G>A p.S2797N | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV63674777; called by muse, mutect2, varscan2
- RYR3 | c.7361G>T p.G2454V (on ENST00000389232; = p.G2455V on NM_001036.6) | Missense Mutation (SNP) | VAF 60/375 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV104430601; called by muse, mutect2, varscan2
- RYR3 | c.10927A>G p.M3643V (on ENST00000389232; = p.M3644V on NM_001036.6) | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs1188536603; called by muse, mutect2, varscan2
- SCN1A | c.563A>G p.D188G | Missense Mutation (SNP) | VAF 45/322 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM011950; called by muse, mutect2, varscan2
- SCTR | c.338C>A p.S113* | Nonsense Mutation (SNP) | VAF 24/173 reads (14%) | catalogued as rs1422210176; called by muse, mutect2, varscan2
- SEC63 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 36/337 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.43); catalogued as rs762056076; called by muse, mutect2, varscan2
- SERINC1 | c.1297G>A p.G433S | Missense Mutation (SNP) | VAF 40/387 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.044); catalogued as COSV60102986; called by muse, mutect2, varscan2
- SHANK2 | c.2477C>A p.P826H | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV53585799; called by muse, mutect2, varscan2
- SLC5A12 | c.130G>T p.G44W | Missense Mutation (SNP) | VAF 57/351 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99744219; called by muse, mutect2, varscan2
- TFAP2D | c.598G>C p.G200R | Missense Mutation (SNP) | VAF 49/293 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV99145661; called by muse, mutect2, varscan2
- TMEM106A | c.83G>A p.S28N | Missense Mutation (SNP) | VAF 71/368 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV57830750; called by muse, mutect2, varscan2
- TNK2 | c.1055G>T p.R352L | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV57370370; called by muse, mutect2, varscan2
- TRGV5 | c.76A>T p.T26S | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.381); catalogued as rs1416127771; called by muse, mutect2, varscan2
- TRPC5 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 87/236 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53301679; called by muse, mutect2, varscan2
- TRPC6 | c.2684G>T p.R895L | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as CM115444, COSV60255633; called by muse, mutect2, varscan2
- WDR90 | c.3553C>T p.H1185Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.558); catalogued as rs1434250397; called by muse, mutect2, varscan2
- ZFP62 | c.482T>C p.I161T (on ENST00000502412 / NM_001377944.1; = p.I128T on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100772705; called by muse, mutect2, varscan2
- ZNF524 | c.720G>T p.W240C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.89); catalogued as rs1202098022; called by muse, varscan2
- ZNF71 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.119); catalogued as rs749081113, COSV100045408, COSV60147634; called by muse, mutect2, varscan2
- ACP4 | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ADAM29 | c.1196G>C p.R399P | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ADAMTS3 | c.3542A>T p.Q1181L | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY8 | c.1385G>T p.G462V | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGB | c.4400C>A p.S1467* | Nonsense Mutation (SNP) | VAF 86/486 reads (18%) | called by muse, mutect2, varscan2
- ADGRL3 | c.1471T>G p.S491A (on ENST00000506720 / NM_001322402.2; = p.S423A on NM_015236.6) | Missense Mutation (SNP) | VAF 54/280 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, varscan2
- AK5 | c.621G>T p.M207I (on ENST00000354567 / NM_174858.3; = p.M181I on NM_012093.4) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ALDOA | c.1109G>A p.G370E (on ENST00000642816 / NM_001243177.4; = p.G316E on NM_184041.5) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALLC | c.81_84+25del p.X27_splice | Splice Site (DEL) | VAF 18/159 reads (11%) | called by mutect2, pindel*
- ANK2 | c.6073G>T p.G2025C | Missense Mutation (SNP) | VAF 46/282 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- AOC1 | c.2086C>A p.L696I | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- APOB | c.11500G>T p.G3834C | Missense Mutation (SNP) | VAF 32/312 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- APOB | c.793C>A p.H265N | Missense Mutation (SNP) | VAF 54/317 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- APPL2 | c.1156del p.V386Sfs*5 | Frame Shift Del (DEL) | VAF 33/195 reads (17%) | called by mutect2, pindel, varscan2
- ATP2C1 | c.6G>A p.K2= | Splice Region (SNP) | VAF 89/437 reads (20%) | called by muse, mutect2, varscan2
- ATP6V0A4 | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 73/380 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- BBS7 | c.1305+1G>T p.X435_splice | Splice Site (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- BIN2 | c.1497del p.T500Pfs*2 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- BSND | c.239T>A p.L80Q | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- C19orf25 | c.312G>T p.M104I | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C20orf85 | c.29C>A p.A10E | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNA1F | c.4715del p.P1572Hfs*17 | Frame Shift Del (DEL) | VAF 12/49 reads (24%) | called by mutect2, pindel, varscan2
- CAPSL | c.220G>T p.V74F | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2
- CASKIN1 | c.2846C>G p.P949R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CASP8AP2 | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.217); called by muse, varscan2
- CASS4 | c.1963C>A p.P655T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by mutect2, varscan2
- CDH1 | c.1184C>A p.T395K | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH18 | c.814C>A p.H272N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, varscan2
- CDHR1 | c.2040+1del | Frame Shift Del (DEL) | VAF 22/156 reads (14%) | called by mutect2, pindel, varscan2
- CEP72 | c.1420G>T p.V474F | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- CFAP47 | c.2551C>A p.L851I | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- CLK3 | c.533A>T p.H178L (on ENST00000395066 / NM_001130028.1; = p.H30L on NM_003992.4) | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CLMP | c.848G>C p.R283P | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- COL14A1 | c.1857T>G p.F619L | Missense Mutation (SNP) | VAF 58/312 reads (19%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.952); called by muse, varscan2
- COL28A1 | c.1058C>A p.S353Y | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- DACT3 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCHS1 | c.879G>T p.E293D | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DHTKD1 | c.83G>C p.R28P | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- DNAH6 | c.5911C>T p.L1971F | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH9 | c.5485C>A p.Q1829K | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- DNAJC6 | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK10 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DSP | c.7719G>T p.M2573I | Missense Mutation (SNP) | VAF 81/321 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENTPD1 | c.27C>A p.S9R | Missense Mutation (SNP) | VAF 71/412 reads (17%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERVFRD-1 | c.780G>T p.M260I | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- EXD1 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.755); called by muse, mutect2
- F13B | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- FAT1 | c.13520G>C p.G4507A | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FBXO43 | c.1651A>G p.T551A | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCGBP | c.5900G>C p.C1967S | Missense Mutation (SNP) | VAF 38/441 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FCSK | c.3108_3116del p.P1037_Q1039del | In Frame Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- FGFRL1 | c.682G>T p.G228C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FLNC | c.3600_3601insA p.E1201Rfs*61 | Frame Shift Ins (INS) | VAF 10/71 reads (14%) | called by mutect2, pindel, varscan2
- FOXI1 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FYCO1 | c.1856G>T p.R619M | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GAS7 | c.1234G>T p.E412* (on ENST00000432992 / NM_201433.2; = p.E272* on NM_003644.3) | Nonsense Mutation (SNP) | VAF 25/92 reads (27%) | called by muse, mutect2, varscan2
- GEN1 | c.385G>C p.V129L | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 29/144 reads (20%) | called by muse, mutect2, varscan2
- GRIN1 | c.2162dup p.R722Efs*78 | Frame Shift Ins (INS) | VAF 5/30 reads (17%) | called by mutect2, pindel
- GRM5 | c.765G>T p.Q255H | Missense Mutation (SNP) | VAF 43/374 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- GSDMC | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 39/393 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- GTF2A1 | c.311A>T p.Q104L | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- HERC5 | c.962G>T p.G321V | Missense Mutation (SNP) | VAF 51/314 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- HIPK1 | c.3102del p.Q1034Hfs*166 (on ENST00000369558 / NM_001369806.1; = p.Q1034Hfs*16 on NM_152696.4) | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, varscan2
- HNRNPA1 | c.751G>C p.G251R | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- IGHV2-70 | c.47G>T p.W16L | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGSF1 | c.3875G>A p.R1292K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ITPR3 | c.6425G>T p.G2142V | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- JARID2 | c.1178T>A p.L393H | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- KCNJ5 | c.352C>A p.L118M | Missense Mutation (SNP) | VAF 74/363 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- KIAA0586 | c.1558A>G p.R520G (on ENST00000619416 / NM_001244190.2; = p.R535G on NM_014749.5) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KIF14 | c.2959C>T p.L987= | Splice Region (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- KLHDC8A | c.946C>A p.R316S | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LCOR | c.4065G>C p.M1355I | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- LRRC7 | c.358T>A p.S120T (on ENST00000651989 / NM_001370785.2; = p.S87T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- LZTFL1 | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- MEAK7 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 61/345 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MRC1 | c.1469C>A p.S490* | Nonsense Mutation (SNP) | VAF 53/392 reads (14%) | called by muse, mutect2, varscan2
- MROH2B | c.1058T>A p.I353N | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- MSMB | c.52T>A p.C18S | Missense Mutation (SNP) | VAF 52/253 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, varscan2
- MUC19 | c.336G>T p.W112C | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- NBPF4 | c.1427C>G p.P476R | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- NCKAP1L | c.1502C>A p.A501D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEIL1 | c.720G>C p.G240= | Splice Region (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- NPR3 | c.1469G>A p.G490E (on ENST00000265074 / NM_001364458.2; = p.G489E on NM_000908.4) | Missense Mutation (SNP) | VAF 98/396 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRP1 | c.1672T>C p.S558P | Missense Mutation (SNP) | VAF 37/276 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- NRP2 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 89/468 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- NRXN1 | c.3133G>T p.A1045S | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NRXN1 | c.3132T>A p.H1044Q | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- NTRK3 | c.1579G>A p.D527N | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- OAS3 | c.3224G>T p.G1075V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- OAZ1 | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OBSCN | c.10298T>A p.V3433E | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- OR10R2 | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR11H2 | c.507G>C p.Q169H (on ENST00000556246; = p.Q180H on NM_001197287.1) | Missense Mutation (SNP) | VAF 74/457 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- OR2L8 | c.817C>A p.L273M | Missense Mutation (SNP) | VAF 36/293 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- OR4C12 | c.239T>A p.I80N | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, varscan2
- OR4K14 | c.399C>A p.Y133* | Nonsense Mutation (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
- OR5T1 | c.949C>A p.L317I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR7D4 | c.401T>G p.V134G | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PARP14 | c.328A>C p.K110Q | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- PCDHAC1 | c.1657C>G p.P553A | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB8 | c.1964C>A p.A655D | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PCLO | c.14761G>T p.A4921S | Missense Mutation (SNP) | VAF 76/434 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PGM2 | c.41G>C p.R14P | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PGR | c.1505C>A p.A502D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- PHF12 | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- PHLDB3 | c.304C>A p.Q102K | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHLPP1 | c.2339A>T p.E780V | Missense Mutation (SNP) | VAF 50/785 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); called by muse, mutect2
- PKD1L3 | c.1707C>A p.C569* | Nonsense Mutation (SNP) | VAF 25/193 reads (13%) | called by muse, mutect2, varscan2
- PLPPR4 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- PPP1R12B | c.41C>A p.S14* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- PRDX1 | c.505_514+4del p.X169_splice | Splice Site (DEL) | VAF 42/192 reads (22%) | called by mutect2, pindel
- PRF1 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- PRKACG | c.182T>A p.V61E | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPN18 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- RBPMS2 | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by mutect2, varscan2
- RELN | c.8969T>G p.L2990R | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- REXO4 | c.998A>G p.K333R | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- RGS18 | c.639G>C p.R213S | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RHD | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 51/296 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- RNF215 | c.289G>T p.D97Y | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2
- RNF32 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- RNGTT | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 14/184 reads (8%) | called by muse, mutect2
- RPL3L | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by mutect2, varscan2
- RPS3 | c.506A>G p.D169G | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SAGE1 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- SERPINE1 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPATA24 | c.17G>C p.G6A | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- SPATA31A6 | c.3709G>A p.A1237T | Missense Mutation (SNP) | VAF 94/576 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.693); called by muse, varscan2
- SPATA31E1 | c.2315A>T p.K772M | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SPTB | c.4621G>A p.G1541R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SRRM4 | c.655del p.R219Efs*39 | Frame Shift Del (DEL) | VAF 22/94 reads (23%) | called by mutect2, pindel, varscan2
- SSC4D | c.22C>A p.L8I | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SVEP1 | c.9617C>A p.S3206* | Nonsense Mutation (SNP) | VAF 33/209 reads (16%) | called by muse, mutect2, varscan2
- SYNE1 | c.13864C>A p.L4622M (on ENST00000367255 / NM_182961.4; = p.L4551M on NM_033071.3) | Missense Mutation (SNP) | VAF 83/712 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- SYT12 | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TBKBP1 | c.1530G>T p.E510D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TDRD5 | c.1964G>A p.G655D | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TG | c.146T>C p.V49A | Missense Mutation (SNP) | VAF 54/734 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- TGM6 | c.1737C>A p.D579E | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- THAP12 | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- TMBIM4 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TNFRSF11A | c.772A>T p.S258C | Missense Mutation (SNP) | VAF 111/1647 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2
- TOP1 | c.1804C>G p.L602V | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TOP2B | c.2044A>T p.R682* (on ENST00000264331 / NM_001330700.2; = p.R677* on NM_001068.3) | Nonsense Mutation (SNP) | VAF 21/194 reads (11%) | called by muse, mutect2, varscan2
- TRIP11 | c.3018T>A p.N1006K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- TTC26 | c.1233G>C p.E411D | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TTN | c.83533C>A p.L27845M (on ENST00000591111; = p.L20421M on NM_003319.4) | Missense Mutation (SNP) | VAF 90/547 reads (16%) | PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- TTN | c.62345C>A p.S20782Y (on ENST00000591111; = p.S13358Y on NM_003319.4) | Missense Mutation (SNP) | VAF 82/391 reads (21%) | PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- TXN | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 87/539 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TYRO3 | c.2148G>A p.W716* | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2, varscan2
- UBE3C | c.2621A>C p.K874T | Missense Mutation (SNP) | VAF 37/250 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- VWDE | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 50/329 reads (15%) | called by muse, mutect2, varscan2
- WDFY3 | c.4450G>C p.D1484H | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- WIZ | c.3779G>T p.W1260L | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- XIRP2 | c.302T>G p.L101R | Missense Mutation (SNP) | VAF 24/218 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, varscan2
- ZBTB44 | c.890A>T p.E297V | Missense Mutation (SNP) | VAF 60/340 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZMYND11 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 32/201 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF283 | c.1729G>T p.G577W | Missense Mutation (SNP) | VAF 38/267 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF541 | c.2448T>A p.N816K | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- ZNF608 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- ZNF618 | c.2689A>T p.T897S (on ENST00000374126 / NM_001318042.2; = p.T804S on NM_133374.2) | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- ZNF721 | c.1567G>A p.G523S (on ENST00000338977; = p.G535S on NM_133474.4) | Missense Mutation (SNP) | VAF 41/325 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF729 | c.3448C>A p.H1150N | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF729 | c.3449A>C p.H1150P | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF84 | c.705T>A p.F235L | Missense Mutation (SNP) | VAF 52/290 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACACB | c.4965G>T p.S1655= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as COSV58140161, COSV58148918; called by muse, mutect2, varscan2
- ACAP3 | c.1377G>T p.T459= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs1371203731; called by muse, mutect2, varscan2
- ACBD5 | c.1347C>T p.I449= (on ENST00000375888 / NM_001352568.1; = p.I440= on NM_145698.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 21/154 reads (14%) | catalogued as rs181926234; called by muse, mutect2, varscan2
- ADGRA1 | c.777C>G p.A259= | Silent (SNP) | VAF 8/44 reads (18%) | called by mutect2, varscan2
- ALKBH3 | c.816G>T p.L272= | Silent (SNP) | VAF 35/281 reads (12%) | called by muse, mutect2, varscan2
- ANKRD30B | c.1953G>T p.L651= | Silent (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2, varscan2
- ANKRD34C | c.1248C>T p.F416= | Silent (SNP) | VAF 19/119 reads (16%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.600C>G p.V200= | Silent (SNP) | VAF 51/353 reads (14%) | called by muse, mutect2, varscan2
- ATP10A | c.3588G>A p.S1196= | Silent (SNP) | VAF 30/202 reads (15%) | catalogued as rs764731676; called by muse, mutect2, varscan2
- BICD1 | c.2727G>A p.R909= | Silent (SNP) | VAF 34/178 reads (19%) | catalogued as rs761821755; called by muse, mutect2, varscan2
- BRAF | c.312G>T p.G104= | Silent (SNP) | VAF 31/168 reads (18%) | called by muse, mutect2, varscan2
- C10orf82 | c.225C>G p.V75= | Silent (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- CCDC74A | c.306A>T p.S102= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV54605267; called by muse, mutect2, varscan2
- CD5L | c.510G>C p.R170= | Silent (SNP) | VAF 29/205 reads (14%) | called by muse, mutect2, varscan2
- CEACAM21 | c.720C>A p.G240= (on ENST00000401445 / NM_001098506.4; = p.G239= on NM_033543.6) | Silent (SNP) | VAF 34/188 reads (18%) | called by muse, mutect2, varscan2
- CYP4A11 | c.1428C>T p.L476= | Silent (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2, varscan2
- CYP4F12 | c.1452G>A p.L484= | Silent (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- DDX60L | c.4062G>T p.L1354= | Silent (SNP) | VAF 77/437 reads (18%) | called by muse, mutect2, varscan2
- DEFB119 | c.216C>G p.T72= | Silent (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- DNAH7 | c.690T>C p.P230= | Silent (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- DNHD1 | c.463A>C p.R155= | Silent (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- EEPD1 | c.1431C>T p.N477= | Silent (SNP) | VAF 47/337 reads (14%) | called by muse, mutect2, varscan2
- ESPL1 | c.2301G>A p.R767= | Silent (SNP) | VAF 33/197 reads (17%) | called by muse, mutect2, varscan2
- FASN | c.1755G>A p.V585= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs751682511; ClinVar: likely benign; called by mutect2, varscan2
- FCER2 | c.651C>A p.T217= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as rs775906963, COSV60916274; called by muse, mutect2, varscan2
- FCRL1 | c.795C>G p.S265= | Silent (SNP) | VAF 20/151 reads (13%) | catalogued as COSV63824632; called by muse, mutect2, varscan2
- FCRL4 | c.1203C>T p.L401= | Silent (SNP) | VAF 37/176 reads (21%) | catalogued as rs780498230; called by muse, mutect2, varscan2
- GGPS1 | c.831A>T p.A277= | Silent (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- KIF18B | c.1014G>C p.T338= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as COSV59270878; called by muse, mutect2, varscan2
- KIRREL2 | c.1344G>C p.L448= | Silent (SNP) | VAF 16/75 reads (21%) | called by muse, mutect2, varscan2
- KPTN | c.117G>T p.G39= | Silent (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- KRT82 | c.897C>T p.I299= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs543851618; called by muse, mutect2, varscan2
- LINGO4 | c.393C>T p.L131= | Silent (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- LPA | c.3529C>A p.R1177= | Silent (SNP) | VAF 52/415 reads (13%) | catalogued as rs1353704684, COSV60302994; called by muse, mutect2, varscan2
- MYO3B | c.1473T>C p.R491= | Silent (SNP) | VAF 104/516 reads (20%) | called by muse, mutect2, varscan2
- NAV3 | c.123T>G p.P41= | Silent (SNP) | VAF 30/161 reads (19%) | called by muse, mutect2, varscan2
- NPPA | c.294G>A p.G98= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1282177282; called by muse, mutect2, varscan2
- NUP98 | c.288C>T p.S96= | Silent (SNP) | VAF 33/254 reads (13%) | called by muse, mutect2, varscan2
- OR10G9 | c.126C>A p.L42= | Silent (SNP) | VAF 21/216 reads (10%) | catalogued as COSV66685701; called by muse, mutect2, varscan2
- OR2A14 | c.108C>A p.L36= | Silent (SNP) | VAF 46/286 reads (16%) | called by muse, mutect2, varscan2
- OR52A5 | c.495C>A p.I165= | Silent (SNP) | VAF 22/130 reads (17%) | called by muse, mutect2, varscan2
- OR8H3 | c.747C>G p.T249= | Silent (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- PDCD4 | c.213T>C p.S71= | Silent (SNP) | VAF 76/437 reads (17%) | catalogued as rs1465287337; called by muse, mutect2, varscan2
- PHF10 | c.210A>G p.P70= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as rs911145294; called by muse, mutect2, varscan2
- PKHD1 | c.1395G>A p.R465= | Silent (SNP) | VAF 104/381 reads (27%) | catalogued as rs1396450370, COSV61893658; called by muse, mutect2, varscan2
- PLCD1 | c.1326C>A p.L442= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs150254083; called by muse, mutect2, varscan2
- PPFIBP2 | c.1140T>C p.A380= | Silent (SNP) | VAF 37/242 reads (15%) | called by muse, mutect2, varscan2
- PROS1 | c.1263G>T p.L421= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as COSV101260465; called by muse, mutect2, varscan2
- PSG3 | c.813C>T p.Y271= | Silent (SNP) | VAF 41/352 reads (12%) | called by muse, mutect2, varscan2
- RAB39A | c.576G>T p.G192= | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- RASGEF1B | c.117C>T p.L39= | Silent (SNP) | VAF 38/217 reads (18%) | catalogued as rs1339104565; called by muse, mutect2, varscan2
- RBM20 | c.1305G>T p.L435= | Silent (SNP) | VAF 36/247 reads (15%) | catalogued as COSV65703901; called by muse, mutect2, varscan2
- SCN2A | c.1989C>A p.L663= | Silent (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2, varscan2
- SF3B1 | c.3459C>T p.F1153= | Silent (SNP) | VAF 21/132 reads (16%) | catalogued as COSV104408101; called by muse, varscan2
- SKOR2 | c.123G>T p.V41= | Silent (SNP) | VAF 78/217 reads (36%) | called by muse, mutect2, varscan2
- SLC49A3 | c.804C>A p.A268= (on ENST00000404286 / NM_001294341.2; = p.A267= on NM_032219.4) | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs922333380, COSV59141996; called by muse, mutect2, varscan2
- SLC7A6 | c.141G>T p.L47= | Silent (SNP) | VAF 64/407 reads (16%) | called by muse, mutect2, varscan2
- SORCS3 | c.720T>C p.Y240= | Silent (SNP) | VAF 39/224 reads (17%) | catalogued as rs764186774; called by muse, mutect2, varscan2
- SPATA31D1 | c.348T>C p.D116= | Silent (SNP) | VAF 24/201 reads (12%) | called by muse, mutect2, varscan2
- SSX2IP | c.192G>A p.Q64= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs376196736; called by muse, varscan2
- SYCP2 | c.2916G>T p.V972= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2
- TMEM132E | c.2592A>T p.A864= (on ENST00000321639; = p.A954= on NM_001304438.2) | Silent (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- TRIM49C | c.957C>A p.P319= | Silent (SNP) | VAF 35/266 reads (13%) | catalogued as COSV101442312; called by muse, mutect2, varscan2
- UNC13A | c.2259G>C p.V753= | Silent (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- VPS13A | c.8274A>T p.V2758= | Silent (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
- VPS13C | c.6729G>A p.S2243= (on ENST00000644861 / NM_020821.3; = p.S2200= on NM_017684.5) | Silent (SNP) | VAF 18/228 reads (8%) | catalogued as rs781402953; called by muse, mutect2
- ZNF2 | c.1293T>C p.R431= (on ENST00000611147 / NM_001291605.2; = p.R418= on NM_021088.4) | Silent (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- ZNF536 | c.3117C>G p.V1039= | Silent (SNP) | VAF 17/135 reads (13%) | catalogued as COSV100836007; called by muse, mutect2, varscan2
- ZNF679 | c.408G>T p.V136= | Silent (SNP) | VAF 25/204 reads (12%) | called by muse, mutect2, varscan2
- ZNF701 | c.1401G>A p.K467= (on ENST00000301093; = p.K401= on NM_018260.3) | Silent (SNP) | VAF 14/185 reads (8%) | called by muse, mutect2
- ZPBP | c.738G>A p.K246= | Silent (SNP) | VAF 25/216 reads (12%) | catalogued as COSV99249521; called by muse, mutect2, varscan2
- AC006288.1 | n.143C>A | RNA (SNP) | VAF 18/147 reads (12%) | called by muse, mutect2, varscan2
- AC100868.1 | c.152-2161G>A | Intron (SNP) | VAF 31/310 reads (10%) | called by muse, mutect2, varscan2
- AC116655.1 | n.181C>G | RNA (SNP) | VAF 10/126 reads (8%) | called by muse, varscan2
- AC133561.1 | n.1965C>A | RNA (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846130 C>A | 5'Flank (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- AL713998.1 | n.180T>C | RNA (SNP) | VAF 22/202 reads (11%) | called by muse, varscan2
- ANK3 | c.12596-420A>G | Intron (SNP) | VAF 32/293 reads (11%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499770 A>G | 5'Flank (SNP) | VAF 6/62 reads (10%) | catalogued as rs1442383076; called by muse, mutect2, varscan2
- ARMC4 | c.1386+2634G>A | Intron (SNP) | VAF 30/190 reads (16%) | called by muse, mutect2, varscan2
- ATP6V1G3 | c.82+3879G>A | Intron (SNP) | VAF 9/72 reads (13%) | catalogued as COSV55279857; called by muse, mutect2, varscan2
- AVPR1A | c.*2014G>T | 3'UTR (SNP) | VAF 25/181 reads (14%) | called by muse, mutect2, varscan2
- BPHL | c.107+482C>T | Intron (SNP) | VAF 60/297 reads (20%) | called by muse, mutect2, varscan2
- BPTF | c.8640-788A>G | Intron (SNP) | VAF 26/221 reads (12%) | called by muse, mutect2, varscan2
- CARD16 | chr11:105045341 T>A | 5'Flank (SNP) | VAF 49/299 reads (16%) | called by muse, mutect2, varscan2
- CCDC74B | c.250+26G>T | Intron (SNP) | VAF 8/100 reads (8%) | called by muse, varscan2
- CCM2L | c.1070-9T>C | Intron (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- CHEK2 | c.721+57G>A | Intron (SNP) | VAF 20/128 reads (16%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56812019 C>A | 3'Flank (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- COL4A1 | c.388-32T>A | Intron (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2, varscan2
- COMTD1 | c.*25G>A | 3'UTR (SNP) | VAF 32/143 reads (22%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*4219dup | 3'UTR (INS) | VAF 11/99 reads (11%) | called by mutect2, pindel, varscan2
- CRHR2 | c.-23T>C | 5'UTR (SNP) | VAF 7/47 reads (15%) | called by muse, varscan2
- DERL3 | c.327+20T>G | Intron (SNP) | VAF 26/162 reads (16%) | called by muse, mutect2, varscan2
- EVC2 | c.-1G>T | 5'UTR (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- GNG2 | c.-29-33209C>A | Intron (SNP) | VAF 42/210 reads (20%) | called by muse, mutect2, varscan2
- GOSR2 | c.-64G>T | 5'UTR (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- GPR162 | c.867+144C>T | Intron (SNP) | VAF 55/277 reads (20%) | called by muse, mutect2, varscan2
- GVINP1 | n.6744G>T | RNA (SNP) | VAF 16/99 reads (16%) | catalogued as rs1487842158; called by muse, mutect2, varscan2
- HOXA7 | chr7:27152889 A>G | 3'Flank (SNP) | VAF 35/271 reads (13%) | catalogued as rs1038837575; called by muse, mutect2, varscan2
- KDM5A | c.165+642T>C | Intron (SNP) | VAF 15/86 reads (17%) | called by muse, mutect2, varscan2
- KIF13B | c.56-4633G>A | Intron (SNP) | VAF 38/167 reads (23%) | called by muse, mutect2, varscan2
- LRRC63 | chr13:46270320 T>C | 3'Flank (SNP) | VAF 32/188 reads (17%) | called by muse, mutect2, varscan2
- MALRD1 | c.4688-251G>C | Intron (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2
- MOCS1 | c.*325C>A | 3'UTR (SNP) | VAF 32/167 reads (19%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1822G>C | RNA (SNP) | VAF 18/159 reads (11%) | called by muse, mutect2, varscan2
- NR1H4 | chr12:100499861 G>T | 5'Flank (SNP) | VAF 42/201 reads (21%) | called by muse, mutect2, varscan2
- PAX6 | c.-40C>A | 5'UTR (SNP) | VAF 21/155 reads (14%) | called by muse, mutect2, varscan2
- PDK3 | chrX:24539138 A>G | 3'Flank (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- PPM1L | c.399+85551G>C | Intron (SNP) | VAF 45/230 reads (20%) | called by muse, mutect2, varscan2
- RPS27 | c.-8A>C | 5'UTR (SNP) | VAF 33/224 reads (15%) | called by muse, mutect2, varscan2
- SERPINF2 | c.*31G>A | 3'UTR (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- ST8SIA3 | c.-237C>A | 5'UTR (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- STMP1 | chr7:135660416 A>G | 5'Flank (SNP) | VAF 43/245 reads (18%) | called by muse, mutect2, varscan2
- SYTL2 | c.1459+1964A>G | Intron (SNP) | VAF 23/175 reads (13%) | called by muse, mutect2, varscan2
- TNN | c.-76A>T | 5'UTR (SNP) | VAF 40/258 reads (16%) | called by muse, mutect2, varscan2
- TTLL6 | c.998+1847G>A | Intron (SNP) | VAF 33/154 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.34264+4774A>T | Intron (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- VAPB | c.*993A>T | 3'UTR (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2, varscan2
- ZFP91 | c.*941T>A | 3'UTR (SNP) | VAF 41/218 reads (19%) | called by muse, mutect2, varscan2
- ZNF849P | n.400T>A | RNA (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- ZSCAN9 | c.569-2186A>T | Intron (SNP) | VAF 28/182 reads (15%) | called by muse, mutect2
- ZZZ3 | c.-89G>T | 5'UTR (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
